Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJO, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJO-TTP1-G (Primary Tumor).

Material description

A. Lung

CDDP-YP-ABJO-01-PR

B. Lymph node

Macro description

A. Right lower lung, lobectomy. Lobe weight 200 grams and lobe size 17 x 11 x 11 cm: in the lateral basal segment there is neoformation coarsely round with biggest diameter of 4 cm and grey yellowish colouring at the surface when you cut. The above pleura is unscathed.

The remaining parenchyma has cottony compactness.

A)neoplasm

B)Margin of bronchial resection and lymph nodes

C)Remainig parenchyma

B. Lymph nodes N1 arrived separately

Micro description

A. A)Moderately differentiated (G2) adenocarcinoma with solid, ^{mucinous} ~~mutinous~~ and papillary aspects

B)Margin of bronchial resection free of neoplasm; peribronchial lymph node with metastases

C)Pulmonary emphysema

B. Metastases

ICD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: (R) lung, lower lobe C34.3

Staging TNM: pI2,pN1

ICD-10

C34.31

Source: NCI Genomic Data Commons file a795a170-0f98-42a8-94fa-cfcf19668f27 (CDDP-ABJO-TTP1.3303BB41-782E-4528-9BE0-D7827CDE4A3E.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).